Surgical pathology report (de-identified scan), TCGA case TCGA-CV-5434, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma), tissue source site MD Anderson Cancer Center, specimen TCGA-CV-5434-01A (Primary Tumor).

[page 1 of 2]
SUPPLEMENTAL REPORT

DIAGNOSIS:

- (A) TOTAL LARYNGECTOMY:
SQUAMOUS CARCINOMA INVADING THYROID CARTILAGE.

DIAGNOSIS

- (A) TOTAL LARYNGECTOMY, BILATERAL NODE DISSECTION II, III, AND IV AND LEFT THYROIDECTOMY:
SQUAMOUS CARCINOMA GRADE 2 INVOLVING LEFT PYRIFORM SINUS, LEFT ARYEPIGLOTTIC FOLD AND PROBABLY THYROID CARTILAGE.
PRESENCE OF PERINEURAL AND LYMPHOVASCULAR INVASION.
Margins of resection free of tumor.
Thyroid gland, no tumor.
METASTATIC SQUAMOUS CARCINOMA IN 7 OF 25 LEFT LYMPH NODES PRESENCE OF EXTRANODAL EXTENSION (4 OF 10 LEVEL II, 3 OF 5 LEVEL III, 0 OF 7 LEVEL IV).
RIGHT NECK LYMPH NODES:
Thirteen lymph nodes, no tumor (0/5 in level II, 0/6 in level III, 0/2 in level IV).
- (B) LEFT BASE OF TONGUE:
Squamous mucosa, no tumor.
- (C) LEFT PHARYNGEAL WALL:
Squamous mucosa, no tumor.

COMMENT

Bone and cartilage were sent for decalcification from the larynx. Supplemental report will follow. A tracheostomy was present.

[page 2 of 2]
GROSS DESCRIPTION

(A) TOTAL LARYNGECTOMY, BILATERAL LEVEL II, III, IV LYMPH NODE DISSECTION AND LEFT THYROIDECTOMY - A total laryngectomy with attached bilateral neck lymph node dissection measures 11.0 x 11.0 x 5.0 cm in toto. The attached left lobe of thyroid is measuring 3.0 x 2.0 x 1.5 cm. A tracheostomy is also present.

An ill-defined tan firm mass measuring 5.0 x 2.0 cm to the depth of 2.0 cm is present at left pyriform sinus with extension to left epiglottic fold. The tumor invades into thyroid cartilage. The tumor is 0.4 cm from the closest left pharyngeal mucosa (additional margin from this side has been additionally submitted (part C). The base of tongue is also submitted separately (part B). The right pharyngeal mucosa is 1.0 cm from the tumor.

The thyroid, laryngeal mucosa, hyoid bone and thyroid are free of tumor.

A portion of the tumor and normal mucosa have been obtained for additional studies.

SECTION CODE: A1-A7, lateral aspect of the tumor sectioned from superior to inferior; A8, left soft tissue margin en face; A9, aryepiglottic fold; A10, medial (right side) pharyngeal mucosa margin perpendicular (margin is inked in blue); A11-A18, medial aspect of the tumor. Sectioned from superior to inferior; A19, tumor invading thyroid bone pending decalcification; A20, left vocal cord; A21, right vocal cord; A22, tracheal margin; A23, tracheostomy; A24, thyroid gland; A25-A29, left level II lymph nodes (A25 six lymph nodes, A26, three lymph nodes, A27 two positive lymph nodes, A28 one positive lymph node, A29 one positive lymph node (the largest positive lymph node measures 1.5 cm in the greatest dimension); A30, three left level III lymph nodes; A31, two positive left level III lymph nodes; A32, four left level IV lymph nodes; A33, three level IV lymph nodes; A34, two right level II lymph nodes; A35, three right level II lymph nodes; A36, four right level III lymph nodes; A37, two right level III lymph nodes; A38, one right level IV lymph node; A39, one right level IV lymph node.

(B) LEFT BASE OF TONGUE - One piece of mucosa, 3 x 0.5 x 0.3 cm. Entirely submitted for frozen section diagnosis in B.

*FS/DX: SQUAMOUS MUCOSA, NO TUMOR PRESENT.

(C) LEFT PHARYNGEAL WALL - One piece of mucosa measuring 7 x 3 x 0.2 cm with attached hemostat which is designated as up end. The up end is inked in blue, and the low end is inked in green.

SECTION CODE: C1, up half of the specimen; C2, lower half of the specimen.

*FS/DX: SQUAMOUS MUCOSA, NO TUMOR PRESENT.

SNOMED CODES

M-80703 T-24100

Source: NCI Genomic Data Commons file 6f362890-da81-432d-8e9b-d80a084e88ad (TCGA-CV-5434.0661B7B0-E677-469B-88C9-0C3E0E250D82.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).